Somatic mutation profile of tumor specimen 0DFPUV from CCDI case PBBSJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.7 years (3,891 days).
Specimen 0DFPUV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b77d5f11-20e9-4492-9dd4-a67612d761e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFPV5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fe61ec0-7421-409c-8d13-93fc28e76296

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 4, Intron 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM3A | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 131/540 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1557219923, COSV104399218; called by muse, mutect2, varscan2
- KIAA0100 | c.3688C>T p.R1230W | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs759113307, COSV66492238; called by muse, mutect2
- MORF4L1 | c.518G>A p.R173Q (on ENST00000331268 / NM_206839.2; = p.R134Q on NM_006791.4) | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV58705900; called by muse, mutect2, varscan2
- PLXNA1 | c.4883G>A p.R1628H | Missense Mutation (SNP) | VAF 205/493 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1265186462, COSV52526680; called by muse, mutect2, varscan2
- RALYL | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 175/486 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749865840, COSV72819608; called by muse, mutect2, varscan2
- SFXN4 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 55/153 reads (36%) | catalogued as COSV53719896; called by muse, mutect2, varscan2
- CPED1 | c.206A>T p.K69I | Missense Mutation (SNP) | VAF 139/643 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- E2F5 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 200/469 reads (43%) | called by muse, mutect2, varscan2
- INPP5J | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 152/464 reads (33%) | called by muse, varscan2
- NOTCH3 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 161/458 reads (35%) | called by muse, mutect2, varscan2
- OLFM3 | c.139A>T p.S47C (on ENST00000338858 / NM_001288821.1; = p.S27C on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PAK3 | c.18T>A p.D6E | Missense Mutation (SNP) | VAF 137/405 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH17 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 18/637 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.189); called by muse, mutect2
- PHLDB1 | c.1210A>T p.S404C | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SGCZ | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 153/361 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SLC26A3 | c.1643A>T p.N548I | Missense Mutation (SNP) | VAF 193/782 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TET3 | c.4131_4132del p.S1379Qfs*29 | Frame Shift Del (DEL) | VAF 120/356 reads (34%) | called by mutect2, pindel, varscan2
- ZNF850 | c.1559T>G p.L520R | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANSL1L | c.2919C>T p.Y973= | Silent (SNP) | VAF 135/362 reads (37%) | catalogued as rs770722712; called by muse, mutect2, varscan2
- LMX1A | c.177C>T p.C59= | Silent (SNP) | VAF 169/650 reads (26%) | catalogued as rs527370820, COSV54220728; called by muse, mutect2, varscan2
- PKHD1 | c.6477C>A p.A2159= | Silent (SNP) | VAF 124/322 reads (39%) | called by muse, mutect2, varscan2
- PKN3 | c.708G>A p.L236= | Silent (SNP) | VAF 183/458 reads (40%) | catalogued as COSV52574713; called by muse, mutect2, varscan2
- MIA3 | c.*56_*60del | 3'UTR (DEL) | VAF 77/163 reads (47%) | called by mutect2, pindel, varscan2
- ST8SIA5 | c.312-27T>C | Intron (SNP) | VAF 123/330 reads (37%) | catalogued as rs746165236; called by muse, mutect2, varscan2
- ZNF692 | c.-12-178T>G | Intron (SNP) | VAF 190/386 reads (49%) | called by muse, mutect2, varscan2
